Somatic mutation profile of tumor specimen MP2PRT-PAUZKH-TMP1-A (aliquot MP2PRT-PAUZKH-TMP1-A-1-0-D-A820-36) from MP2PRT case MP2PRT-PAUZKH, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.7 years (2,460 days).
Specimen MP2PRT-PAUZKH-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 489c1c12-41af-4d04-ac8e-39f698da01f0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUZKH-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUZKH-NB1-A-1-0-D-A820-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/005fd38d-82e6-43f7-9c4e-dc217a51c87d

The open-access MAF lists 13 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Frame Shift Ins 2, Silent 2, RNA 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.124A>G p.T42A | Missense Mutation (SNP) | VAF 44/284 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.411); catalogued as rs397507501, CM021125, COSV61008667; ClinVar: pathogenic; called by muse, varscan2
- EPHA8 | c.503C>T p.T168M | Missense Mutation (SNP) | VAF 129/411 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs142239276; called by muse, mutect2, varscan2
- KSR2 | c.277C>T p.R93W | Missense Mutation (SNP) | VAF 55/326 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.448); catalogued as rs1480626870, COSV60394666; called by muse, mutect2, varscan2
- TRAF3 | c.139G>A p.V47M | Missense Mutation (SNP) | VAF 54/351 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.137); catalogued as rs755721963, COSV61026712; called by muse, mutect2, varscan2
- ZFHX3 | c.10793del p.P3598Lfs*96 | Frame Shift Del (DEL) | VAF 81/265 reads (31%) | catalogued as rs774585182; called by mutect2, pindel, varscan2
- CCDC73 | c.1820T>A p.L607H | Missense Mutation (SNP) | VAF 84/237 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DDX20 | c.2056_2058delinsTCTGAACG p.E686Sfs*36 | Frame Shift Ins (INS) | VAF 60/257 reads (23%) | called by pindel, varscan2*
- HCFC2 | c.2125G>T p.E709* | Nonsense Mutation (SNP) | VAF 18/338 reads (5%) | called by muse, mutect2
- PANX2 | c.68A>G p.E23G | Missense Mutation (SNP) | VAF 174/438 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- RTN4 | c.2850_2851insCA p.L951Hfs*15 | Frame Shift Ins (INS) | VAF 58/345 reads (17%) | called by mutect2, pindel, varscan2
- CEP170B | c.633C>A p.A211= (on ENST00000453495; = p.A140= on NM_015005.3) | Silent (SNP) | VAF 91/467 reads (19%) | called by muse, mutect2, varscan2
- GRID2 | c.798C>T p.N266= | Silent (SNP) | VAF 74/205 reads (36%) | catalogued as rs755074343, COSV56180903; called by muse, mutect2, varscan2
- DCHS2 | n.7803G>A | RNA (SNP) | VAF 34/491 reads (7%) | catalogued as rs373906914; called by muse, mutect2
